Somatic mutation profile of tumor specimen MMRF_2222_1_BM_CD138pos (aliquot MMRF_2222_1_BM_CD138pos_T1_KHS5U_L09514) from MMRF case MMRF_2222, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.2 years (16,880 days).
Specimen MMRF_2222_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1028b915-247b-403c-8d33-1f9fd2d18b50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2222_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2222_1_PB_Whole_C2_KHS5U_L09513; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ca9c0d-7a28-4ee3-a4dd-49d65758f22c

The open-access MAF lists 90 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 23, Silent 13, Intron 12, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV53257934; called by muse, mutect2
- ATP6V0C | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV53550087; called by muse, mutect2
- CAND2 | c.1999del p.A667Lfs*55 (on ENST00000456430 / NM_001162499.2; = p.A574Lfs*55 on NM_012298.3) | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | catalogued as COSV99929198; called by mutect2, pindel, varscan2
- CLCN1 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771890096, COSV58371451; called by muse, mutect2, varscan2
- ERI2 | c.1958del p.P653Hfs*23 | Frame Shift Del (DEL) | VAF 88/279 reads (32%) | catalogued as COSV99184577; called by pindel, varscan2
- FUT3 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as rs761087037, COSV54605782; called by muse, mutect2
- FZD6 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145774645; called by muse, mutect2
- GBP1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV65084739; called by muse, mutect2
- H1-1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 244/382 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.486); catalogued as rs778104178; called by muse, mutect2, varscan2
- IGHV2-70 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.816); catalogued as rs375927713; called by muse, varscan2
- IGKV2D-30 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs752404955; called by muse, mutect2, varscan2
- IGLV3-1 | c.157T>G p.W53G | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs186777494; called by muse, varscan2
- IGLV3-1 | c.196A>C p.I66L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs537896918; called by muse, varscan2
- MUC16 | c.36662G>A p.S12221N | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.35); catalogued as rs1463662542, COSV67474599; called by muse, mutect2, varscan2
- MUC5B | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1241372270, COSV71592389; called by muse, mutect2, varscan2
- NEXMIF | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV50021603, COSV99281227, COSV99281597; called by muse, mutect2
- NUTM1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774746499; called by muse, mutect2, varscan2
- PCDH15 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 135/332 reads (41%) | catalogued as COSV57304981; called by muse, mutect2, varscan2
- PDGFRA | c.2186G>C p.G729A | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV57265152; called by muse, mutect2, varscan2
- PGAP3 | c.253C>G p.H85D | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs939290151; called by muse, mutect2, varscan2
- RASD2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759035874, COSV53351941; called by muse, mutect2, varscan2
- SHB | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1262940111, COSV66629036; called by muse, mutect2
- SLC7A13 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs144691522; called by muse, mutect2, varscan2
- C2orf49 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- C9orf57 | c.100T>G p.F34V (on ENST00000377024 / NM_001371610.1; = p.F12V on NM_001128618.2) | Missense Mutation (SNP) | VAF 17/367 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); called by muse, mutect2
- CASD1 | c.991T>G p.Y331D | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- COL6A6 | c.2686G>C p.D896H | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.498); called by muse, mutect2
- DBT | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DPP4 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- EPB41L5 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GABBR1 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- LIMCH1 | c.2326C>T p.R776* | Nonsense Mutation (SNP) | VAF 92/249 reads (37%) | called by muse, mutect2, varscan2
- LRRC3 | c.600C>G p.H200Q | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B2 | c.44T>A p.L15* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- SCAND1 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TTC7A | c.1186_1203del p.Y396_E401del | In Frame Del (DEL) | VAF 56/142 reads (39%) | called by mutect2, pindel, varscan2
- UGT2A3 | c.1102G>C p.A368P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YTHDC1 | c.1717G>T p.D573Y (on ENST00000344157 / NM_001031732.4; = p.D555Y on NM_133370.4) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAM9 | c.2113C>T p.L705= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- ANO9 | c.198C>T p.H66= | Silent (SNP) | VAF 48/186 reads (26%) | called by muse, mutect2, varscan2
- AR | c.1212G>A p.A404= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as rs773692090; called by muse, mutect2, varscan2
- CSNK1G2 | c.198C>G p.L66= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- DNAH1 | c.10662C>T p.I3554= | Silent (SNP) | VAF 122/409 reads (30%) | called by muse, mutect2, varscan2
- GPLD1 | c.1740T>C p.F580= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- KIF25 | c.240G>A p.S80= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs34379899; called by muse, mutect2, varscan2
- MON2 | c.4947C>T p.V1649= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- OR3A1 | c.69G>A p.A23= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs150014531; called by muse, mutect2, varscan2
- PCDHGA1 | c.705A>G p.A235= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs754390986; called by mutect2, varscan2
- RNF38 | c.1547G>A p.*516= | Silent (SNP) | VAF 116/458 reads (25%) | called by muse, varscan2
- SCMH1 | c.1885C>T p.L629= (on ENST00000326197 / NM_001031694.2; = p.L560= on NM_012236.4) | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs750227720; called by muse, mutect2, varscan2
- VRTN | c.1596C>T p.R532= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- AIFM3 | c.*321T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs1281918633; called by muse, mutect2, varscan2
- ANKRD36 | c.1430-900_1430-891delinsCATATAC | Intron (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2*
- AP3M1 | c.*355A>C | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ARMH4 | c.*1161C>T | 3'UTR (SNP) | VAF 32/81 reads (40%) | catalogued as rs1055356541; called by muse, mutect2, varscan2
- BCAR3 | c.*182T>A | 3'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, varscan2
- C11orf45 | c.*569G>A | 3'UTR (SNP) | VAF 9/177 reads (5%) | catalogued as rs1243060259; called by muse, mutect2
- C2orf91 | n.3279C>T | RNA (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- C6orf120 | c.*862G>A | 3'UTR (SNP) | VAF 41/101 reads (41%) | catalogued as rs1022559078; called by muse, mutect2, varscan2
- CALM2 | c.*657T>A | 3'UTR (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.*709T>G | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- CIPC | c.307-31G>A | Intron (SNP) | VAF 94/236 reads (40%) | called by muse, mutect2, varscan2
- CNPY2 | c.*412A>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- CTNND2 | c.*325C>T | 3'UTR (SNP) | VAF 10/87 reads (11%) | catalogued as rs1487439227; called by muse, mutect2, varscan2
- CYP3A7 | c.*46A>C | 3'UTR (SNP) | VAF 120/270 reads (44%) | called by muse, mutect2, varscan2
- DCTN3 | c.352+11G>A | Intron (SNP) | VAF 28/781 reads (4%) | called by muse, mutect2
- DPH2 | c.261-96A>C | Intron (SNP) | VAF 146/299 reads (49%) | called by muse, mutect2, varscan2
- FNBP4 | c.1820+113T>G | Intron (SNP) | VAF 32/44 reads (73%) | called by muse, varscan2
- G3BP1 | c.*4133T>C | 3'UTR (SNP) | VAF 39/41 reads (95%) | called by muse, mutect2, varscan2
- GPX8 | c.*2327C>T | 3'UTR (SNP) | VAF 7/76 reads (9%) | catalogued as rs1200620574; called by muse, mutect2, varscan2
- HMBS | c.34-183G>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- HS1BP3 | c.623+3458C>A | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.*79A>G | 3'UTR (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8078A>C | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
- INO80D | c.*7869T>C | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- MIA3 | c.*970_*972del | 3'UTR (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- MIR5195 | chr14:106851346 A>G | 5'Flank (SNP) | VAF 60/128 reads (47%) | catalogued as rs1199406372; called by muse, mutect2, varscan2
- NT5E | c.*1135G>T | 3'UTR (SNP) | VAF 51/78 reads (65%) | called by muse, mutect2, varscan2
- NTN4 | c.-33G>T | 5'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as rs973873204; called by muse, mutect2, varscan2
- OPN5 | c.*683T>C | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- PIK3C3 | c.*1379G>T | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- PIK3CG | c.-6T>A | 5'UTR (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*81T>C | 3'UTR (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- RTN1 | c.1974-19G>T | Intron (SNP) | VAF 13/26 reads (50%) | catalogued as rs1469175095; called by muse, mutect2, varscan2
- SEMA3E | c.*2547T>G | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- TBR1 | c.1191-55C>A | Intron (SNP) | VAF 72/149 reads (48%) | called by muse, varscan2
- TLN1 | c.*74G>A | 3'UTR (SNP) | VAF 9/127 reads (7%) | catalogued as rs1004854357, COSV59210757; called by muse, mutect2
- TUB | c.156-110C>T | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2
- YAF2 | c.306-73T>C | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- ZNF99 | c.*929A>G | 3'UTR (SNP) | VAF 17/190 reads (9%) | catalogued as rs71357935; called by muse, mutect2
